TARGET case TARGET-40-NAAFKH — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8c158573-ad05-50f5-a45a-b7ca22ed9a3c

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 43 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C41.9; Tissue or organ of origin: Bone, NOS; Classification of tumor: primary; Age at diagnosis: 43.9 years (16,037 days); Year of diagnosis: 2011; Days to last follow up: 1,462 days (4.0 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,462.

Biospecimens (1 sample)
- Sample TARGET-40-NAAFKH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_20230709.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1462
- Specific tumor site: Bone NOS

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAFKH-01A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 98
- % Non Tumor Nuclei: Top from Biopsy: 2
- % Cellular Tumor: Top from Biopsy: 89
- % Normal: Top from Biopsy: 1
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 10
- % Tumor Nuclei: Bottom from Biopsy: 98
- % Non Tumor Nuclei: Bottom from Biopsy: 2
- % Cellular Tumor: Bottom from Biopsy: 89
- % Normal: Bottom from Biopsy: 1
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 10
- PASS/FAIL: pass
